TCGA case TCGA-12-0773 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df4168bd-9f94-4323-9c33-a446a9fae999

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 24 years; Vital status: Dead; Days to death: 1,315 days (3.6 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 24.2 years (8,849 days); Year of diagnosis: 2003; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Monoclonal Antibody 81C6; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 56 days; Treatment dose: 10 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 56 days; Treatment dose: 61 mCi.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 90 days; Days to treatment end: 140 days; Treatment dose: 6,000 cGy; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 150 days; Days to treatment end: 245 days; Number of cycles: 2; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 235 days; Days to treatment end: 326 days; Number of cycles: 2; Treatment dose: 83 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 326 days; Days to treatment end: 431 days (1.2 years); Number of cycles: 2; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 431 days (1.2 years); Days to treatment end: 516 days (1.4 years); Number of cycles: 2; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 516 days (1.4 years); Days to treatment end: 607 days (1.7 years); Number of cycles: 2; Treatment dose: 83 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 607 days (1.7 years); Days to treatment end: 725 days (2.0 years); Treatment dose: 100 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 773 days (2.1 years); Days to treatment end: 875 days (2.4 years); Number of cycles: 2; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 892 days (2.4 years); Days to treatment end: 1,015 days (2.8 years); Number of cycles: 2; Treatment dose: 83 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,015 days (2.8 years); Days to treatment end: 1,036 days (2.8 years); Number of cycles: 1; Treatment dose: 38 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,062 days (2.9 years); Days to treatment end: 1,141 days (3.1 years); Number of cycles: 2; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,141 days (3.1 years); Days to treatment end: 1,274 days (3.5 years); Treatment dose: 10 mg/kg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,141 days (3.1 years); Days to treatment end: 1,274 days (3.5 years); Number of cycles: 2; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,274 days (3.5 years); Days to treatment end: 1,311 days (3.6 years); Number of cycles: 2; Treatment dose: 50 mg/m2; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 26.2 years (9,574 days); Days to diagnosis: 725 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 748 days (2.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 725 (post initial treatment): Progression or recurrence: Yes; Days to progression: 725 days (2.0 years).
- Days to follow up: 1,311 days (3.6 years); Disease response: With Tumor.
- Days to follow up: 1,315 days (3.6 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.3; Shortest dimension: 0.3.
  Slide TCGA-12-0773-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 0.
  Slide TCGA-12-0773-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-12-0773-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0773-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 5: Pharmaceutical therapy drug name: VP-16.
- Drug treatment 8: Pharmaceutical therapy drug name: Temozolamide.
- Drug treatment 10: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 10, Route of administrations: Route of administration: IV.
- Drug treatment 12: Pharmaceutical therapy drug name: MAb I-131.
- Drug treatment 14: Pharmaceutical therapy drug name: MU81C6.
- Drug treatment 15: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 16: Pharmaceutical therapy drug name: mu81c6.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,315 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,315 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 725 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0773-01A-01D-0333-01): tumor purity 0.84, ploidy 2.16, whole-genome doublings 0.
